Somatic mutation profile of tumor specimen 0D9XFB from CCDI case PBBJGC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 12.7 years (4,644 days).
Specimen 0D9XFB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef871400-b095-4e1c-9394-9dc620a07306.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9XFC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/743d967b-42de-488f-b9ab-4cd0402e046c

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 3, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GOLGA6L10 | c.709T>C p.C237R | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1247552231; called by muse, varscan2
- CCDC141 | c.1783G>C p.D595H | Missense Mutation (SNP) | VAF 360/946 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, varscan2
- ZNF658 | c.3073G>C p.D1025H | Missense Mutation (SNP) | VAF 70/362 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.382); called by muse, varscan2
- CDH15 | c.939G>A p.T313= | Silent (SNP) | VAF 124/396 reads (31%) | catalogued as rs769047556, COSV99228351; called by muse, varscan2
- GOLGA6L10 | c.708G>A p.L236= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs770900517; called by muse, varscan2
- ZNF831 | c.2529C>T p.T843= | Silent (SNP) | VAF 54/152 reads (36%) | called by muse, varscan2
- FGFR1 | c.358+91C>G | Intron (SNP) | VAF 19/40 reads (48%) | called by muse, varscan2
- SLC39A8 | chr4:102259456 G>A | 3'Flank (SNP) | VAF 50/496 reads (10%) | catalogued as rs753160208; called by muse, varscan2
